Somatic mutation profile of tumor specimen 0DQ7VC from CCDI case PBCENA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mesenchymal chondrosarcoma; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 12.6 years (4,585 days).
Specimen 0DQ7VC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d571fcb2-3ddd-43c2-bec6-edccf91efd23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7V3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61ea2984-13ce-45fa-bf26-e69acca695d9

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAM2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 432/935 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs370187720; called by muse, mutect2, varscan2
- LRP5 | c.4729C>T p.P1577S | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53718341; called by muse, mutect2, varscan2
- NUP210 | c.2927C>T p.S976L | Missense Mutation (SNP) | VAF 215/456 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756348715; called by muse, mutect2, varscan2
- PLA2G12A | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 85/774 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs1197205762; called by muse, mutect2, varscan2
- PUSL1 | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 29/317 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs144003672, COSV60089489, COSV60090111; called by muse, mutect2
- ZMIZ1 | c.2525C>A p.S842Y | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV57888913; called by muse, mutect2, varscan2
- ALS2 | c.3860T>C p.V1287A | Missense Mutation (SNP) | VAF 265/627 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GPRC6A | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 81/716 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- PSG4 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 242/546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GSDMC | c.735C>T p.S245= | Silent (SNP) | VAF 231/577 reads (40%) | catalogued as rs765277111, COSV52699751; called by muse, mutect2, varscan2
- KLK3 | c.147C>A p.V49= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV100385905; called by muse, mutect2, varscan2
- MSANTD4 | c.321C>T p.L107= | Silent (SNP) | VAF 91/774 reads (12%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1095C>T p.A365= | Silent (SNP) | VAF 126/376 reads (34%) | catalogued as COSV50658566; called by muse, mutect2, varscan2
- PLA2G4F | c.2295G>A p.L765= | Silent (SNP) | VAF 24/293 reads (8%) | called by muse, mutect2
- ZBED3 | c.630C>T p.P210= | Silent (SNP) | VAF 142/274 reads (52%) | catalogued as rs775892271; called by muse, mutect2, varscan2
- CDR2 | c.-50C>T | 5'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- LRIT1 | c.*27C>T | 3'UTR (SNP) | VAF 60/112 reads (54%) | called by muse, mutect2, varscan2
